Gene-level copy-number profile of tumor specimen TCGA-29-1764-01A from TCGA case TCGA-29-1764, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 49.3 years (18,012 days).
Specimen TCGA-29-1764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.286c3c1e-c00f-4d29-b805-ecd1432a6a78.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1764-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c31d9694-5095-4d7a-95e8-0802f41a9ccf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 1,680; copy number 2: 13,178; copy number 3: 17,116; copy number 4: 14,879; copy number 5: 8,522; copy number 6: 3,038; copy number 7: 873; copy number 8: 171; copy number 9: 235; copy number 11: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1764-01A-01D-0559-01): tumor purity 0.58, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–5,509,126, 73 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,334 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,108,056–53,467,488, 646 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:38,814–7,261,504, 102 genes, copy number 9 (broad region; genes not listed).
- chr6:167,607–11,516,466, 227 genes, copy number 7 (broad region; genes not listed).
- chr8:125,859,721–145,066,685, 359 genes, copy number 8–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,027. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
